Somatic mutation profile of tumor specimen TCGA-06-0221-02A (aliquot TCGA-06-0221-02A-11D-2280-08) from TCGA case TCGA-06-0221, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.0 years (11,333 days).
Specimen TCGA-06-0221-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ff1d3fb-3960-498b-a10b-439b5c92065a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0221-10A (Blood Derived Normal), aliquot TCGA-06-0221-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cc566d5-6edd-4b05-a283-96ba8aebaaf9

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Frame Shift Del 5, In Frame Del 2, Nonsense Mutation 2, Splice Site 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 35/120 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.8017T>A p.L2673I | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as COSV101446776; called by muse, mutect2, varscan2
- ADAMTS16 | c.604del p.H202Tfs*20 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as COSV56987127; called by mutect2, pindel, varscan2
- ATRX | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 87/114 reads (76%) | catalogued as COSV64869924; called by muse, mutect2, varscan2
- CCDC149 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1268753550, COSV60878484; called by muse, mutect2, varscan2
- CD19 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs374321123; called by muse, mutect2, varscan2
- CFAP57 | c.1432T>A p.S478T | Missense Mutation (SNP) | VAF 112/290 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV63016765; called by muse, mutect2, varscan2
- FGL1 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs189727691; called by muse, mutect2
- HOMER3 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374896199; called by muse, mutect2, varscan2
- KRT1 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52868030; called by muse, mutect2, varscan2
- MUC16 | c.36673G>T p.A12225S | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.139); catalogued as rs761851478, COSV67479438; called by muse, mutect2, varscan2
- OR52K2 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 88/133 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV57835488; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs200840736, COSV53452285; called by muse, mutect2, varscan2
- PTPRZ1 | c.6072G>T p.E2024D | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.493); catalogued as rs754717245, COSV101099889; called by muse, mutect2, varscan2
- RSPO3 | c.313T>A p.C105S | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63151930; called by muse, mutect2, varscan2
- SIGLEC11 | c.1485G>T p.E495D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as COSV70222075; called by muse, mutect2, varscan2
- SLCO6A1 | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 114/261 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.044); catalogued as COSV65812666; called by muse, mutect2, varscan2
- SZRD1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374711991; called by muse, mutect2, varscan2
- ZFP57 | c.985T>C p.S329P | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV65306555; called by muse, mutect2, varscan2
- ZNF254 | c.1864A>G p.R622G | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs1244560554, COSV61643716; called by muse, mutect2, varscan2
- ZNF787 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1273033477, COSV99555331; called by muse, mutect2
- ANXA1 | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- C6 | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESF1 | c.1208T>A p.V403E | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FN1 | c.1031A>G p.E344G | Missense Mutation (SNP) | VAF 168/397 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRIA4 | c.685_696del p.G229_V232del | In Frame Del (DEL) | VAF 20/49 reads (41%) | called by pindel, varscan2
- HECTD2 | c.1040_1044del p.H347Rfs*55 | Frame Shift Del (DEL) | VAF 49/148 reads (33%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.6308T>C p.L2103S | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGFN1 | c.2323_2334del p.I775_Y778del (on ENST00000295591 / NM_001367841.1; = p.I3232_Y3235del on NM_001164586.2) | In Frame Del (DEL) | VAF 41/132 reads (31%) | called by mutect2, pindel, varscan2
- LIN28A | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- NALCN | c.4201C>T p.Q1401* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- NCOR1 | c.3527G>C p.G1176A | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCOR1 | c.3526G>T p.G1176C | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- NFATC2 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE4DIP | c.3202_3208del p.S1068Dfs*13 | Frame Shift Del (DEL) | VAF 43/282 reads (15%) | called by mutect2, varscan2
- RYR2 | c.13882G>T p.G4628C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- SGSM2 | c.2475-3_2477delinsT p.X825_splice (on ENST00000426855 / NM_001098509.2; = p.X870_splice on NM_014853.3) | Splice Site (DEL) | VAF 79/369 reads (21%) | called by pindel, varscan2*
- SLC1A3 | c.336_348del p.D112Efs*9 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- TP53 | c.417_418del p.K139Nfs*9 | Frame Shift Del (DEL) | VAF 65/111 reads (59%) | called by mutect2, pindel, varscan2
- ZNF443 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARHGAP10 | c.2091C>T p.S697= | Silent (SNP) | VAF 13/157 reads (8%) | called by muse, mutect2
- CYB561D2 | c.51T>C p.T17= | Silent (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- DOCK10 | c.1371G>T p.G457= | Silent (SNP) | VAF 91/185 reads (49%) | catalogued as COSV51420916; called by muse, mutect2, varscan2
- FCRL1 | c.984C>T p.Y328= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs200953593; called by muse, mutect2, varscan2
- KCNU1 | c.495G>A p.K165= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV67757887; called by muse, mutect2, varscan2
- LRRC34 | c.432G>A p.A144= | Silent (SNP) | VAF 65/160 reads (41%) | catalogued as rs147903682; called by muse, mutect2, varscan2
- MGA | c.7560A>G p.K2520= (on ENST00000219905 / NM_001164273.1; = p.K2311= on NM_001080541.2) | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV54958369; called by muse, mutect2, varscan2
- SBF2 | c.2304C>T p.L768= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as rs758341369, COSV56314394; called by muse, mutect2, varscan2
- SECISBP2L | c.75T>C p.S25= | Silent (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- TESK1 | c.522C>T p.R174= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs755675303, COSV52411742; called by muse, mutect2, varscan2
- TLL2 | c.1587G>A p.T529= | Silent (SNP) | VAF 51/139 reads (37%) | catalogued as rs151335014; called by muse, mutect2, varscan2
- TRAK1 | c.1341C>T p.S447= (on ENST00000327628 / NM_001349247.2; = p.S389= on NM_014965.5) | Silent (SNP) | VAF 75/209 reads (36%) | called by muse, mutect2, varscan2
- C3P1 | n.3228G>T | RNA (SNP) | VAF 37/127 reads (29%) | called by muse, mutect2, varscan2
- DERL3 | c.*1939del | 3'UTR (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
